Gene-level copy-number profile of tumor specimen TCGA-AA-3495-01A from TCGA case TCGA-AA-3495, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 79.1 years (28,886 days).
Specimen TCGA-AA-3495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.835e8d77-c667-4585-a3f7-acf271e33bd3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3495-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85ac47ed-39de-4274-b814-ec59ff8441e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,555; copy number 2: 44,198; copy number 3: 5,921; copy number 4: 719; copy number 5: 2,844; copy number 6: 404; copy number 7: 178.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3495-01): tumor purity 0.57, ploidy 2.25, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,404 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:11,820,317–18,027,846, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr7:18,127,220–18,127,309, 1 gene, copy number 6: MIR1302-6.
- chr7:19,695,461–20,827,753, 20 genes, copy number 6: POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8.
- chr7:20,843,627–20,843,961, 1 gene, copy number 6: RPS26P30.
- chr7:21,543,039–33,877,180, 256 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:42,661,716–48,669,479, 130 genes, copy number 5 (broad region; genes not listed).
- chr7:49,773,638–71,713,600, 431 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:83,363,238–88,306,894, 42 genes, copy number 5: SEMA3E, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4.
- chr7:91,638,847–96,709,891, 89 genes, copy number 6 (broad region; genes not listed).
- chr8:38,062,881–145,066,685, 1,678 genes, copy number 5 (broad region; genes not listed).
- chr20:30,484,925–52,670,578, 597 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:56,730,397–60,814,211, 90 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
